Gene-level copy-number profile of tumor specimen ALCH-B2MR-TTP1-A from ALCHEMIST case ALCH-B2MR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.9 years (24,788 days).
Specimen ALCH-B2MR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 41907885-a3b0-493b-8f54-069a3f6399ed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2MR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/1f23355c-56cf-4fc2-8e83-4ab7f78eaf39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 344; copy number 1: 17,820; copy number 2: 34,821; copy number 3: 3,831; copy number 4: 1,629; copy number 5: 233; copy number 6: 91; copy number 7: 84; copy number 8: 42; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 236 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:800,879–1,361,777, 56 genes (within-gene range 0–1): AL669831.4, FAM87B, LINC01128, LINC00115, AL669831.7, FAM41C, TUBB8P11, AL669831.5, AL645608.6, AL645608.2, AL645608.4, LINC02593, SAMD11, NOC2L, KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223, C1orf159, AL390719.3, LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1, UBE2J2, LINC01786, SCNN1D, ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808, MXRA8.
- chr1:2,425,980–2,591,469, 11 genes (within-gene range 0–1): PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B.
- chr1:3,454,665–3,611,508, 4 genes: ARHGEF16, AL512413.1, MEGF6, MIR551A.
- chr1:223,181,144–223,188,154, 1 gene: AL359979.1.
- chr3:11,745–858,091, 11 genes: LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr4:49,486,926–49,506,022, 2 genes: AC119751.3, ANKRD20A17P.
- chr4:49,561,479–49,562,149, 1 gene: SNX18P24.
- chr5:104,773,641–104,799,772, 2 genes (within-gene range 0–2): AC099520.2, RNU6-334P.
- chr8:12,064,389–12,071,747, 1 gene: DEFB130B.
- chr8:12,178,697–12,194,133, 2 genes: ALG1L11P, FAM86B1.
- chr9:134,317,098–134,440,585, 2 genes: RXRA, MIR4669.
- chr11:777,578–784,297, 3 genes: AP006621.3, AP006621.5, AP006621.2.
- chr13:113,815,630–113,845,744, 1 gene (within-gene range 0–1): GAS6-AS1.
- chr15:21,990,074–22,282,872, 19 genes (within-gene range 0–1): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, AC025884.3, MIR1268A, AC025884.2, AC025884.1.
- chr15:79,141,939–79,298,235, 4 genes: ANKRD34C-AS1, MIR184, HNRNPCP3, ANKRD34C.
- chr16:525,155–1,510,457, 92 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:1,512,979–1,555,580, 3 genes (within-gene range 0–1): AL031705.1, TMEM204, AL031719.1.
- chr17:13,095,695–13,100,939, 1 gene: AC005303.1.
- chr17:81,976,807–82,098,294, 11 genes: ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN.
- chr17:82,314,868–82,334,074, 2 genes: CD7, SECTM1.
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–2): MIR4758.
- chr20:63,540,810–63,547,504, 2 genes: SRMS, AL121829.2.
- chr21:8,603,547–8,680,934, 2 genes: RPSAP68, CR381572.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 452 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,446–522,928, 14 genes, copy number 6: AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene, copy number 6: AC114498.1.
- chr1:161,070,998–161,605,662, 38 genes, copy number 6–7 (within-gene range 3–7): NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C.
- chr1:161,683,695–163,769,691, 44 genes, copy number 5: RPL31P11, Y_RNA, FCRLA, FCRLB, RN7SL466P, DUSP12, AL359541.1, ATF6, AL391825.1, OLFML2B, AL590408.1, NOS1AP, AL450163.1, MIR4654, AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1.
- chr2:89,286,689–89,600,680, 7 genes, copy number 5: IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr8:12,043,506–12,043,670, 1 gene, copy number 5: DEFB131C.
- chr8:12,095,176–12,099,536, 1 gene, copy number 6: DEFB108D.
- chr8:37,326,575–39,417,378, 67 genes, copy number 5 (broad region; genes not listed).
- chr8:39,522,976–40,016,391, 11 genes, copy number 5: AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1.
- chr8:47,089,572–47,960,178, 20 genes, copy number 5 (within-gene range 3–5): AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1.
- chr8:110,766,863–116,766,925, 29 genes, copy number 5 (within-gene range 4–5): AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H.
- chr8:139,600,838–141,195,808, 19 genes, copy number 5: KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr14:28,765,640–36,656,163, 147 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr14:36,677,921–40,390,547, 45 genes, copy number 6–8 (within-gene range 1–8): SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1.
- chr22:18,605,355–18,719,341, 8 genes, copy number 6–9: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 15,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
